Somatic mutation profile of tumor specimen TCGA-CQ-6221-01A (aliquot TCGA-CQ-6221-01A-11D-2078-08) from TCGA case TCGA-CQ-6221, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; Tumor grade: G3; Age at diagnosis: 79.5 years (29,026 days).
Specimen TCGA-CQ-6221-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55112242-8192-4204-bc15-59259fd15b39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-6221-10A (Blood Derived Normal), aliquot TCGA-CQ-6221-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9cb8be55-282f-45e5-9025-bba7ea98516d

The open-access MAF lists 125 somatic variants for this specimen: 101 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 22, Nonsense Mutation 10, Frame Shift Del 8, Splice Site 2, Splice Region 1, 3'UTR 1, Intron 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 19/26 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA2 | c.4865C>G p.P1622R (on ENST00000614293; = p.P1592R on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV99688326; called by muse, mutect2, varscan2
- ABCA3 | c.3938C>G p.S1313* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100069033, COSV100069191; called by muse, mutect2, varscan2
- ADAM17 | c.1555A>T p.S519C | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100176481; called by muse, mutect2, varscan2
- ADGRL3 | c.3197C>T p.S1066L (on ENST00000506720 / NM_001322402.2; = p.S998L on NM_015236.6) | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101547369; called by muse, mutect2, varscan2
- AHNAK | c.10861G>A p.E3621K | Missense Mutation (SNP) | VAF 81/164 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.218); catalogued as COSV99949214; called by muse, mutect2, varscan2
- AHNAK | c.10705G>A p.E3569K | Missense Mutation (SNP) | VAF 88/144 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV99949218; called by muse, mutect2, varscan2
- AHNAK | c.9360G>A p.M3120I | Missense Mutation (SNP) | VAF 94/195 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99949220; called by muse, mutect2, varscan2
- AHNAK | c.6910G>C p.E2304Q | Missense Mutation (SNP) | VAF 85/176 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.327); catalogued as COSV99949232; called by muse, mutect2, varscan2
- AHNAK | c.6153G>T p.M2051I | Missense Mutation (SNP) | VAF 142/274 reads (52%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99949236; called by mutect2, varscan2
- AHNAK | c.5251G>A p.D1751N | Missense Mutation (SNP) | VAF 77/141 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.116); catalogued as COSV99949239; called by muse, mutect2, varscan2
- ALDH1A2 | c.299C>G p.S100* | Nonsense Mutation (SNP) | VAF 48/210 reads (23%) | catalogued as COSV99991049; called by muse, mutect2, varscan2
- ALK | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV101202579; called by muse, mutect2
- ALOXE3 | c.638C>G p.S213* | Nonsense Mutation (SNP) | VAF 21/69 reads (30%) | catalogued as COSV100559915; called by muse, mutect2, varscan2
- AMER1 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 51/83 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100366931; called by muse, mutect2, varscan2
- BRD4 | c.2159-1G>A p.X720_splice | Splice Site (SNP) | VAF 38/117 reads (32%) | catalogued as COSV54592932; called by muse, mutect2, varscan2
- C2orf16 | c.4495G>C p.E1499Q | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.844); catalogued as COSV100820957; called by muse, mutect2, varscan2
- CACNA1A | c.2560G>A p.G854S | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1270399331, COSV64195313; called by muse, mutect2, varscan2
- CALHM2 | c.855C>G p.Y285* | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | catalogued as COSV99588788; called by muse, mutect2, varscan2
- CELSR2 | c.6134C>G p.S2045* | Nonsense Mutation (SNP) | VAF 3/39 reads (8%) | catalogued as COSV54769318, COSV99604601; called by muse, mutect2
- CHD5 | c.1111G>C p.D371H | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV99312995, COSV99314750; called by muse, mutect2
- CLK1 | c.266G>C p.R89P | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100362417, COSV58435581; called by muse, mutect2, varscan2
- CSNK1E | c.811C>G p.Q271E | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as COSV100725084; called by muse, mutect2, varscan2
- CSNK1G1 | c.1105C>G p.Q369E | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.41); catalogued as COSV100274406; called by muse, mutect2
- CUBN | c.10493G>A p.R3498H | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs143300012; called by muse, mutect2, varscan2
- DHRS13 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 21/64 reads (33%) | catalogued as COSV100242090, COSV60457217; called by muse, mutect2, varscan2
- DNER | c.1663G>C p.G555R | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as COSV59161849, COSV59168801; called by muse, mutect2, varscan2
- EFCAB14 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100905663; called by muse, mutect2, varscan2
- EIF3E | c.122A>C p.K41T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99623455; called by muse, mutect2, varscan2
- EPN1 | c.899C>T p.P300L (on ENST00000270460 / NM_001321263.1; = p.P275L on NM_013333.3) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs964187672, COSV50037967, COSV99322294; called by muse, mutect2, varscan2
- FAM160B2 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV99249200; called by muse, mutect2, varscan2
- FAM193A | c.3623-1G>C p.X1208_splice (on ENST00000324666 / NM_001256666.1; = p.X1167_splice on NM_003704.3) | Splice Site (SNP) | VAF 29/85 reads (34%) | catalogued as COSV100219529; called by muse, mutect2, varscan2
- FAT3 | c.4456G>C p.D1486H | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99970133; called by muse, mutect2, varscan2
- FBN3 | c.6245G>T p.R2082L | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.992); catalogued as COSV99561674; called by muse, mutect2
- FBXW7 | c.1547G>A p.S516N (on ENST00000281708 / NM_001349798.2; = p.S436N on NM_018315.5) | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99660222; called by muse, mutect2, varscan2
- FIBIN | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as rs144159497, COSV100590534; called by muse, mutect2, varscan2
- FRMD7 | c.1177C>G p.L393V | Missense Mutation (SNP) | VAF 74/113 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as COSV100049229; called by muse, mutect2, varscan2
- FZD2 | c.1275C>G p.F425L | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.01); catalogued as COSV100190466, COSV59528545; called by muse, mutect2, varscan2
- GBP7 | c.627C>T p.G209= | Splice Region (SNP) | VAF 12/87 reads (14%) | catalogued as rs1465954170, COSV99643411; called by muse, mutect2, varscan2
- GGA1 | c.396C>G p.I132M | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100289850, COSV57331349; called by muse, mutect2, varscan2
- GPC5 | c.86C>T p.T29I | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs1015791528, COSV100995545; called by muse, mutect2
- GPR155 | c.1352A>G p.Y451C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as COSV99790188; called by muse, mutect2, varscan2
- GPR39 | c.969G>T p.M323I | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100258391, COSV61416159; called by muse, mutect2, varscan2
- H1-3 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.926); catalogued as rs1266069764, COSV55096890; called by muse, mutect2, varscan2
- HSPA4 | c.1540C>T p.Q514* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV100507668; called by muse, mutect2, varscan2
- HYDIN | c.14862G>C p.Q4954H | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV101125199; called by muse, mutect2, varscan2
- IGHV4-28 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.343); catalogued as rs782123813; called by muse, varscan2
- IKBKB | c.1397C>G p.S466C | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV100645812; called by muse, mutect2, varscan2
- INTS2 | c.2056C>G p.Q686E | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.81); PolyPhen benign (0.265); catalogued as COSV99248505, COSV99248657; called by muse, mutect2, varscan2
- ITGAX | c.1547A>T p.H516L | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99191990; called by muse, mutect2, varscan2
- KIF1B | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs561371619, COSV99824041; called by muse, mutect2
- KMT2D | c.3668C>G p.S1223* | Nonsense Mutation (SNP) | VAF 29/72 reads (40%) | catalogued as COSV99985270; called by muse, mutect2, varscan2
- KRT10 | c.867G>C p.E289D | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs946515647, COSV99510263; called by muse, mutect2, varscan2
- LALBA | c.282C>G p.I94M | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV99974317, COSV99974463; called by muse, mutect2, varscan2
- LIF | c.543G>C p.K181N | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50777265, COSV99969977; called by muse, mutect2, varscan2
- MAP3K7 | c.1329G>C p.L443F (on ENST00000369329 / NM_145331.3; = p.L416F on NM_003188.4) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.795); catalogued as COSV100997552; called by muse, mutect2, varscan2
- MCF2L2 | c.1753G>A p.D585N | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100193722; called by muse, mutect2, varscan2
- MED12 | c.12C>G p.F4L | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.16); PolyPhen benign (0.28); catalogued as COSV100379617; called by muse, mutect2, varscan2
- MSRA | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100413661, COSV57812420; called by muse, mutect2, varscan2
- MSTN | c.86A>G p.Q29R | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.003); catalogued as COSV99640812; called by muse, mutect2, varscan2
- MTF1 | c.2225A>G p.E742G | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV100888701; called by muse, mutect2
- MYPN | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100590489, COSV62737821; called by muse, mutect2, varscan2
- NINJ2 | c.110T>C p.M37T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs749901093, COSV99843485; called by muse, mutect2, varscan2
- NLRP3 | c.1186C>G p.L396V | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as rs906785956, COSV60219321; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOS1 | c.2027dup p.C677Lfs*38 | Frame Shift Ins (INS) | VAF 10/17 reads (59%) | catalogued as rs746543323; called by mutect2, varscan2
- OPLAH | c.3439G>T p.D1147Y | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101470885; called by muse, mutect2, varscan2
- PDHX | c.409G>C p.D137H | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV99927881; called by muse, mutect2, varscan2
- PIK3C2B | c.2705T>A p.M902K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.131); catalogued as COSV100916207; called by muse, mutect2
- PROSER1 | c.1838G>T p.S613I | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100612999, COSV61487052; called by muse, mutect2, varscan2
- RAB32 | c.139del p.H47Tfs*45 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as COSV100832353; called by mutect2, pindel, varscan2
- RAG1 | c.240G>C p.L80F | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100201104, COSV55026247; called by muse, mutect2, varscan2
- RBPJ | c.1339G>C p.E447Q | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV100623728, COSV100623839, COSV60757568; called by muse, mutect2, varscan2
- ROS1 | c.2078G>A p.S693N | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV100877634, COSV63855169; called by muse, mutect2, varscan2
- SEMA6D | c.1865G>A p.R622Q | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs545257336, COSV100317491; called by muse, mutect2, varscan2
- SH3BGRL2 | c.181C>G p.Q61E | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.334); catalogued as COSV100877640, COSV63964854; called by muse, mutect2, varscan2
- SLC6A13 | c.1375G>T p.V459L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.169); catalogued as COSV100570044; called by muse, mutect2, varscan2
- SNX9 | c.839A>G p.N280S | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as rs1562614634, COSV101094135; called by muse, mutect2, varscan2
- SOGA1 | c.1516G>C p.G506R | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.977); catalogued as rs769793681, COSV99414705, COSV99414991; called by muse, varscan2
- SORT1 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as rs747520170, COSV99860692; called by muse, mutect2, varscan2
- STPG1 | c.355G>C p.D119H (on ENST00000337248 / NM_001199013.2; = p.D72H on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV99134365; called by muse, mutect2
- TTC14 | c.2272G>A p.A758T | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99870386; called by muse, mutect2
- ULK2 | c.2095G>C p.D699H | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100860943; called by muse, mutect2, varscan2
- UNC13C | c.4930G>T p.E1644* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV99522202; called by muse, mutect2, varscan2
- USP37 | c.1263C>G p.F421L | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51442096, COSV99294796; called by muse, mutect2, varscan2
- VPS13D | c.11336G>C p.R3779T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as COSV99169214; called by muse, mutect2, varscan2
- WTAP | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV100603393; called by muse, mutect2, varscan2
- YWHAQ | c.498C>G p.I166M | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99431406; called by muse, mutect2, varscan2
- ZDHHC8 | c.1394T>C p.F465S | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV100273130; called by muse, mutect2
- ZNF319 | c.795G>T p.K265N | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99540424; called by muse, mutect2, varscan2
- ZNF324B | c.59C>G p.T20R | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.398); catalogued as rs760720393, COSV100351775; called by muse, mutect2, varscan2
- ZPBP2 | c.901C>G p.P301A (on ENST00000348931 / NM_199321.3; = p.P279A on NM_198844.3) | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100818563, COSV62375481; called by muse, mutect2, varscan2
- AHNAK | c.2018_2060del p.L673Cfs*4 | Frame Shift Del (DEL) | VAF 34/124 reads (27%) | called by mutect2, pindel
- CELSR2 | c.8355_8388del p.G2786Qfs*28 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | called by mutect2, pindel
- DDX52 | c.865C>G p.L289V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- DNAH3 | c.2974_2986del p.E992Qfs*16 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | called by mutect2, pindel
- EHHADH | c.1693_1706del p.L565Tfs*8 | Frame Shift Del (DEL) | VAF 18/117 reads (15%) | called by mutect2, pindel
- FBXL7 | c.1334del p.G445Afs*15 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- HTR3D | c.1046_1056del p.L349Hfs*16 (on ENST00000382489 / NM_001163646.2; = p.L174Hfs*16 on NM_182537.3) | Frame Shift Del (DEL) | VAF 21/113 reads (19%) | called by mutect2, pindel, varscan2
- METTL1 | c.731_750del p.V244Efs*100 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | called by mutect2, pindel, varscan2
- MMP28 | c.1484C>G p.A495G | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2
- TERF2 | c.1207_1215del p.R403_V405del | In Frame Del (DEL) | VAF 12/37 reads (32%) | called by mutect2, pindel, varscan2
- ACSM1 | c.978G>A p.Q326= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV99533345; called by muse, mutect2, varscan2
- AEN | c.129G>A p.R43= | Silent (SNP) | VAF 23/28 reads (82%) | catalogued as COSV100237592; called by muse, mutect2, varscan2
- AHNAK | c.8931G>A p.V2977= | Silent (SNP) | VAF 67/139 reads (48%) | catalogued as rs879178350, COSV99949223; called by muse, mutect2, varscan2
- ARMC4 | c.804A>T p.G268= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99518971; called by muse, mutect2, varscan2
- ATP8B2 | c.735C>T p.S245= (on ENST00000672630; = p.S212= on NM_001005855.2) | Silent (SNP) | VAF 108/278 reads (39%) | catalogued as rs142408071, COSV100528194; called by muse, mutect2, varscan2
- CAMTA1 | c.1938G>C p.T646= | Silent (SNP) | VAF 57/235 reads (24%) | catalogued as rs142993717, COSV57917025; called by muse, mutect2, varscan2
- ENAM | c.2340G>A p.P780= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs376148809; called by muse, mutect2, varscan2
- GRIK3 | c.1626C>A p.I542= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as COSV100902253; called by muse, mutect2, varscan2
- HEATR5B | c.51C>T p.I17= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs1430154550, COSV99247885; called by muse, mutect2, varscan2
- MID2 | c.714A>G p.K238= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as COSV99465448; called by muse, mutect2, varscan2
- MYOCD | c.1393C>T p.L465= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as COSV100591292; called by muse, mutect2, varscan2
- OAS2 | c.1296C>A p.V432= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100660293; called by muse, mutect2, varscan2
- PAG1 | c.630G>C p.S210= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV99597827; called by muse, mutect2, varscan2
- PRDM15 | c.1191G>A p.S397= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as rs1198596452, COSV99520842; called by muse, mutect2, varscan2
- REV3L | c.7026C>T p.L2342= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV100725614; called by muse, mutect2, varscan2
- SGSH | c.1200G>A p.Q400= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV100413575; called by muse, mutect2, varscan2
- SPG11 | c.6414C>T p.V2138= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99969388; called by muse, mutect2
- TIMM10B | c.168G>C p.L56= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV99601626; called by muse, mutect2, varscan2
- UBR5 | c.4695T>A p.V1565= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV99642107; called by muse, mutect2, varscan2
- UGT2B4 | c.627G>A p.E209= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as rs1302720649, COSV100522608; called by muse, mutect2, varscan2
- ULK2 | c.1962G>A p.Q654= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as COSV100860944; called by muse, mutect2, varscan2
- ZNF382 | c.255T>C p.D85= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV99498049; called by muse, mutect2, varscan2
- EIF4A2 | c.771+35C>T | Intron (SNP) | VAF 53/137 reads (39%) | catalogued as rs202149708, COSV99961341; called by muse, mutect2, varscan2
- LRP1B | c.*2C>G | 3'UTR (SNP) | VAF 7/29 reads (24%) | catalogued as COSV101259957; called by muse, mutect2
